Somatic mutation profile of tumor specimen 760f15d2-444c-4deb-b133-62f3ca (aliquot 760f15d2-444c-4deb-b133-62f3ca_D6) from CPTAC case 01CO001, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC.
Specimen 760f15d2-444c-4deb-b133-62f3ca: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38bd19bb-7ab7-4e1d-8f98-181d70b4f2d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 32a96c14-8234-45e7-b15b-085a13 (Blood Derived Normal), aliquot 32a96c14-8234-45e7-b15b-085a13_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d80304a-3ffc-4dba-a65e-34ce57bda09b

The open-access MAF lists 92 somatic variants for this specimen: 62 protein-altering or splice-affecting, 21 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 21, Splice Site 3, 3'UTR 3, Frame Shift Del 3, 5'Flank 2, RNA 2, Splice Region 2, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3982C>T p.Q1328* | Nonsense Mutation (SNP) | VAF 150/426 reads (35%) | hotspot (GDC flag); catalogued as rs398123121, CM930028, COSV57324976; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs796053126, CM139611, COSV51835030; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 54/309 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519739, COSV61684417, COSV61684645, COSV61684738; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 103/381 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WDR45 | c.974-1G>A p.X325_splice (on ENST00000376372 / NM_001029896.2; = p.X326_splice on NM_007075.3) | Splice Site (SNP) | VAF 16/46 reads (35%) | catalogued as rs1557083830; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACP7 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 354/468 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs542948386, COSV58699954; called by muse, mutect2, varscan2
- ADAMTS16 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 39/368 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752870234; called by muse, mutect2, varscan2
- ADAMTS5 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.501); catalogued as rs367992476, COSV53177630; called by mutect2, varscan2
- ADGRG4 | c.7295C>T p.T2432M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs143014685; called by muse, varscan2
- ADIPOQ | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750108412; called by muse, mutect2, varscan2
- AKAP13 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs779495573, COSV100773513; called by muse, mutect2, varscan2
- CARMIL1 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV61517172; called by muse, mutect2, varscan2
- CD1D | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 111/371 reads (30%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as COSV63810023; called by muse, mutect2, varscan2
- COL6A3 | c.2231C>T p.P744L | Missense Mutation (SNP) | VAF 49/449 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs199504304; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- ETV1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs772105404, COSV54136587; called by muse, mutect2, varscan2
- EVC2 | c.1528T>G p.L510V | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as rs1391810700, COSV100185092; called by muse, mutect2
- FBXW7 | c.1787C>T p.S596F (on ENST00000281708 / NM_001349798.2; = p.S516F on NM_018315.5) | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55905007, COSV55968840, COSV55969630; called by muse, mutect2, varscan2
- GRIN2A | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV58022206; called by muse, mutect2, varscan2
- HS3ST2 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54457921; called by muse, mutect2, varscan2
- KATNIP | c.3161G>A p.R1054Q | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs765345877; called by muse, mutect2, varscan2
- KCP | c.2261G>A p.R754H (on ENST00000620378; = p.R814H on NM_001366122.1) | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs554345022; called by muse, mutect2, varscan2
- LAMA4 | c.4169G>A p.R1390Q (on ENST00000230538 / NM_001105206.3; = p.R1383Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.034); catalogued as rs200468893, COSV57899601; called by muse, mutect2, varscan2
- LRRTM3 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV63671170; called by muse, mutect2, varscan2
- MCTP2 | c.871A>G p.I291V | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs766199285; called by mutect2, varscan2
- MUC16 | c.33118G>A p.G11040R | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.157); catalogued as COSV67501983; called by muse, mutect2, varscan2
- NSUN6 | c.232-1G>A p.X78_splice | Splice Site (SNP) | VAF 18/94 reads (19%) | catalogued as rs765997175, COSV101045803; called by muse, mutect2, varscan2
- PALLD | c.1623C>T p.A541= | Splice Region (SNP) | VAF 18/122 reads (15%) | catalogued as COSV99824139; called by mutect2, varscan2
- PNMT | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54093434; called by muse, mutect2, varscan2
- RB1CC1 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs761572592, COSV50245344; called by muse, mutect2, varscan2
- SEZ6L | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs1211422692, COSV50660109, COSV99962860; called by muse, mutect2, varscan2
- SMAD4 | c.1049T>A p.V350D | Missense Mutation (SNP) | VAF 56/309 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM135256, COSV61684103, COSV61697788; called by muse, mutect2
- SORCS3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762674027, COSV63804506; called by muse, varscan2
- SPNS3 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs778569653; called by muse, mutect2, varscan2
- SVOPL | c.1008C>G p.C336W (on ENST00000419765; = p.C184W on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55994687; called by muse, mutect2, varscan2
- TRPV1 | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs199704222, COSV51516230; called by muse, mutect2, varscan2
- TSSC4 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs760640459; called by muse, mutect2, varscan2
- UNC5A | c.1972G>A p.D658N | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs751456892, COSV99459732; called by muse, mutect2, varscan2
- WDR81 | c.1062C>A p.H354Q | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100488938; called by muse, mutect2, varscan2
- ABCA8 | c.416T>A p.F139Y | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ADGRG4 | c.8275G>A p.G2759R | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AHRR | c.829T>A p.S277T | Missense Mutation (SNP) | VAF 39/357 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.408); called by mutect2, varscan2
- ALDH16A1 | c.1936C>A p.Q646K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.893); called by muse, mutect2
- APOL2 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CADPS | c.3401T>G p.I1134R | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CDKN2AIP | c.858del p.E287Rfs*15 | Frame Shift Del (DEL) | VAF 28/191 reads (15%) | called by mutect2, pindel, varscan2
- CHST7 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAM205A | c.3688G>T p.G1230W | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); called by mutect2, varscan2
- HSD17B7P2 | n.314+7C>T | Splice Region (SNP) | VAF 22/133 reads (17%) | called by muse, mutect2, varscan2
- INSC | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KLF17 | c.81+1G>A p.X27_splice | Splice Site (SNP) | VAF 10/86 reads (12%) | called by muse, varscan2
- MAGEE1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MRC2 | c.3350C>T p.P1117L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NAB1 | c.752A>T p.K251I | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- NTRK2 | c.1906G>A p.A636T (on ENST00000323115 / NM_001369534.1; = p.A652T on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/371 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNX3 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPN22 | c.1138T>A p.F380I (on ENST00000359785 / NM_001193431.2; = p.F325I on NM_012411.5) | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PTPRZ1 | c.1261T>G p.L421V | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- PZP | c.2425A>G p.I809V | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.085); called by muse, mutect2
- RAD21 | c.1307A>G p.Q436R | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMG9 | c.763_767del p.G255Rfs*29 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.431del p.G144Afs*43 | Frame Shift Del (DEL) | VAF 65/292 reads (22%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.3734T>C p.L1245S | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2
- C1orf167 | c.4350C>T p.A1450= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as rs1045085128; called by muse, mutect2, varscan2
- CDH20 | c.687C>T p.N229= | Silent (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- CNGA4 | c.588C>T p.F196= | Silent (SNP) | VAF 39/248 reads (16%) | catalogued as rs377739445; called by muse, varscan2
- CTTN | c.24C>T p.H8= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as rs142607453; called by muse, mutect2, varscan2
- DUOX1 | c.3417C>A p.V1139= | Silent (SNP) | VAF 52/324 reads (16%) | called by muse, mutect2, varscan2
- ERBB4 | c.3237G>A p.V1079= | Silent (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- GPR179 | c.3147C>T p.D1049= (on ENST00000621958; = p.D1048= on NM_001004334.4) | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs377070318; called by muse, mutect2, varscan2
- ITPR1 | c.129C>T p.T43= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as rs771630186; called by muse, mutect2, varscan2
- KIF17 | c.1338C>T p.D446= | Silent (SNP) | VAF 54/306 reads (18%) | catalogued as rs765789636; called by muse, mutect2, varscan2
- KRT25 | c.1017G>A p.A339= | Silent (SNP) | VAF 84/316 reads (27%) | catalogued as rs753281617, COSV56443647; called by muse, mutect2, varscan2
- LOXL3 | c.753G>A p.T251= | Silent (SNP) | VAF 94/374 reads (25%) | catalogued as rs756534259, COSV51217580; called by muse, mutect2, varscan2
- MAMDC4 | c.3648G>A p.P1216= (on ENST00000445819; = p.P1137= on NM_206920.3) | Silent (SNP) | VAF 21/232 reads (9%) | catalogued as rs138000291; called by muse, mutect2
- MITF | c.1440C>T p.D480= (on ENST00000448226 / NM_006722.3; = p.D380= on NM_000248.4) | Silent (SNP) | VAF 28/159 reads (18%) | catalogued as rs756305763, COSV58830674; called by muse, mutect2, varscan2
- PCDHB7 | c.1476G>A p.P492= | Silent (SNP) | VAF 102/558 reads (18%) | catalogued as rs782340324; called by muse, mutect2
- PTPRQ | c.3891T>G p.T1297= (on ENST00000616559; = p.T1255= on NM_001145026.2) | Silent (SNP) | VAF 14/179 reads (8%) | catalogued as COSV57032472; called by muse, mutect2
- RASGRF2 | c.2025C>T p.A675= | Silent (SNP) | VAF 24/432 reads (6%) | catalogued as rs148519927; called by muse, mutect2
- REPIN1 | c.1365C>G p.P455= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs1432142957; called by muse, mutect2, varscan2
- STEAP4 | c.1260C>T p.Y420= | Silent (SNP) | VAF 36/217 reads (17%) | catalogued as rs528338063, COSV57330652; called by muse, mutect2, varscan2
- TIGD3 | c.981G>A p.S327= | Silent (SNP) | VAF 31/222 reads (14%) | called by muse, mutect2, varscan2
- TMPRSS11A | c.678C>T p.V226= | Silent (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- ZNF536 | c.489C>T p.C163= | Silent (SNP) | VAF 34/380 reads (9%) | catalogued as rs1427014287, COSV62818202; called by muse, mutect2
- AL772337.1 | n.857+70T>C | Intron (SNP) | VAF 46/340 reads (14%) | called by muse, mutect2, varscan2
- AXIN1 | c.*19G>A | 3'UTR (SNP) | VAF 83/500 reads (17%) | catalogued as rs202184209; called by muse, mutect2, varscan2
- CCDC144CP | n.2395del | RNA (DEL) | VAF 27/256 reads (11%) | called by mutect2, pindel, varscan2
- CNKSR1 | chr1:26177507 A>G | 5'Flank (SNP) | VAF 19/111 reads (17%) | catalogued as rs1557617412; called by muse, mutect2, varscan2
- CNTN4 | c.*49C>G | 3'UTR (SNP) | VAF 10/223 reads (4%) | called by muse, mutect2
- LRATD1 | c.*381T>G | 3'UTR (SNP) | VAF 62/268 reads (23%) | called by muse, mutect2, varscan2
- RPL23AP42 | n.185G>A | RNA (SNP) | VAF 37/311 reads (12%) | catalogued as rs765127668; called by muse, mutect2, varscan2
- TRIM74 | chr7:72969858 C>T | 5'Flank (SNP) | VAF 17/173 reads (10%) | catalogued as rs782068140; called by muse, mutect2, varscan2
- TRPM2 | c.3462-1285C>T | Intron (SNP) | VAF 26/131 reads (20%) | catalogued as rs191684960, COSV55968348; called by muse, mutect2, varscan2
